Somatic mutation profile of tumor specimen HCM-CSHL-0426-C18-86A (aliquot HCM-CSHL-0426-C18-86A-01D-A937-36) from HCMI case HCM-CSHL-0426-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-CSHL-0426-C18-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c59eeb46-7b0d-4873-999a-c04c261337d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0426-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0426-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77d073c4-b27d-40ac-88ff-7fb50917264c

The open-access MAF lists 3,369 somatic variants for this specimen: 2,481 protein-altering or splice-affecting, 738 silent, 150 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,754, Silent 738, Frame Shift Del 461, Frame Shift Ins 117, Nonsense Mutation 101, Intron 94, 3'UTR 21, Splice Region 19, 5'UTR 15, In Frame Del 14, Splice Site 12, 5'Flank 11.

Variants (750 of 3,369; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 150/283 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, varscan2
- APC | c.465del p.D156Tfs*14 | Frame Shift Del (DEL) | VAF 98/238 reads (41%) | catalogued as rs1554071529; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 144/393 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 80/180 reads (44%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 130/138 reads (94%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 135/341 reads (40%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KCNQ2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs796052630; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 301/703 reads (43%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 217/511 reads (42%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LIPA | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 182/399 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776472526, CM993352, CM995150; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561dup p.R521Pfs*15 | Frame Shift Ins (INS) | VAF 234/491 reads (48%) | catalogued as rs767319284; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 96/255 reads (38%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDK3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs397515323, CM132388, COSV64792933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 172/372 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PNPO | c.556C>T p.R186W (on ENST00000225573; = p.R229W on NM_018129.4) | Missense Mutation (SNP) | VAF 233/449 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894629, CM051610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 101/253 reads (40%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 113/333 reads (34%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 298/420 reads (71%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RSPH4A | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 154/352 reads (44%) | catalogued as rs755782051, CM1515267, COSV57635223; ClinVar: pathogenic; called by muse, varscan2
- RYR1 | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118192175, CM981780; ClinVar: risk factor / pathogenic / drug response; called by muse, mutect2, varscan2
- SCN2A | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 240/522 reads (46%) | catalogued as rs1060503102, COSV51837686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD5 | c.3855dup p.S1286Lfs*37 | Frame Shift Ins (INS) | VAF 134/320 reads (42%) | catalogued as rs1553641476; ClinVar: likely pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 101/229 reads (44%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 192/428 reads (45%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, varscan2
- A2ML1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367937691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAMDC | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 195/383 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs368865821; called by muse, mutect2, varscan2
- AATK | c.3611C>T p.A1204V (on ENST00000326724 / NM_001080395.3; = p.A1101V on NM_004920.2) | Missense Mutation (SNP) | VAF 245/504 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1338608572; called by muse, mutect2, varscan2
- ABCA13 | c.10508del p.N3503Tfs*28 | Frame Shift Del (DEL) | VAF 150/368 reads (41%) | catalogued as rs759644486; called by mutect2, pindel, varscan2
- ABCA6 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as COSV52635421; called by muse, mutect2, varscan2
- ABCC1 | c.1345del p.L449Cfs*12 | Frame Shift Del (DEL) | VAF 221/538 reads (41%) | catalogued as rs1567347647; called by mutect2, pindel, varscan2
- ABCC11 | c.3443T>C p.M1148T | Missense Mutation (SNP) | VAF 216/448 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs936473292; called by muse, mutect2, varscan2
- ABCC2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 185/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747449108, COSV64985390; called by muse, mutect2, varscan2
- ABCC4 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 192/397 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV65313010; called by muse, mutect2, varscan2
- ABCF3 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs140602070; called by muse, varscan2
- ABCG1 | c.1076del p.G359Vfs*5 | Frame Shift Del (DEL) | VAF 183/484 reads (38%) | catalogued as rs1569239566, CM138401; called by mutect2, pindel, varscan2
- ABHD15 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 224/508 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1165093398; called by muse, varscan2
- ABTB1 | c.712C>T p.R238W (on ENST00000232744 / NM_172027.3; = p.R96W on NM_032548.3) | Missense Mutation (SNP) | VAF 226/470 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs756189995, COSV51739923; called by muse, mutect2, varscan2
- AC069544.2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 17/368 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); catalogued as rs1223417724; called by muse, mutect2
- AC099489.1 | c.6653C>T p.T2218I | Missense Mutation (SNP) | VAF 196/397 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1235267574; called by muse, mutect2, varscan2
- AC100868.1 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as rs750827898; called by muse, mutect2
- AC138647.1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 43/660 reads (7%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.029); catalogued as rs556016453; called by muse, mutect2
- ACADVL | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 181/337 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs374729641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACO2 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV53443990; called by muse, mutect2, varscan2
- ACP6 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 201/448 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs201634452, COSV65077341; called by muse, mutect2, varscan2
- ACSL3 | c.131del p.F44Sfs*17 | Frame Shift Del (DEL) | VAF 116/288 reads (40%) | catalogued as COSV62484662; called by mutect2, pindel, varscan2
- ACSM2A | c.305G>A p.G102D (on ENST00000219054; = p.G23D on NM_001308169.2) | Missense Mutation (SNP) | VAF 223/680 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs745993663; called by muse, varscan2
- ACTN3 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 143/371 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs563563593; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 224/227 reads (99%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 130/312 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM12 | c.708del p.V237Lfs*5 | Frame Shift Del (DEL) | VAF 139/369 reads (38%) | catalogued as COSV64108477; called by mutect2, pindel, varscan2
- ADAMTS7 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 198/498 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376444243; called by muse, varscan2
- ADAMTSL1 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 162/304 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs957824765; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 188/372 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1178409619; called by muse, mutect2, varscan2
- ADCY4 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 195/394 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566439285, COSV60258900; called by muse, mutect2, varscan2
- ADCY7 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs754927240, COSV54270471; called by muse, mutect2, varscan2
- ADGRA2 | c.3251G>A p.C1084Y | Missense Mutation (SNP) | VAF 28/612 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55103340; called by muse, mutect2
- ADGRB2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57079113; called by muse, mutect2, varscan2
- ADGRE1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 223/413 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.156); catalogued as rs375499219; called by muse, mutect2, varscan2
- ADGRL3 | c.2645T>G p.F882C (on ENST00000506720 / NM_001322402.2; = p.F814C on NM_015236.6) | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101547327; called by muse, mutect2, varscan2
- ADH1A | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 25/507 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1349900171; called by muse, mutect2
- AEN | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 135/295 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs146671175; called by muse, mutect2, varscan2
- AFAP1L2 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs145837129; called by muse, varscan2
- AGAP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 126/275 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs373781245; called by muse, mutect2, varscan2
- AGAP1 | c.2059A>G p.S687G (on ENST00000304032 / NM_001037131.3; = p.S634G on NM_014914.5) | Missense Mutation (SNP) | VAF 177/328 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs763397001; called by muse, mutect2, varscan2
- AGRN | c.2780C>T p.T927I | Missense Mutation (SNP) | VAF 238/483 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs1298843399, COSV65072296; called by muse, mutect2, varscan2
- ALK | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 313/619 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs779147984, COSV66580573; called by muse, mutect2, varscan2
- ALYREF | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 215/433 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58669325; called by muse, mutect2, varscan2
- AMDHD1 | c.1139_1140dup p.G381Tfs*23 | Frame Shift Ins (INS) | VAF 200/431 reads (46%) | catalogued as rs778433337; called by mutect2, varscan2
- AMER3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 242/498 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as rs1326472040; called by muse, varscan2
- AMPH | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 126/271 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375161752; called by muse, mutect2, varscan2
- ANGPTL2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 209/477 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs756824904; called by muse, mutect2, varscan2
- ANK1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 313/616 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs751082142, COSV55883941; called by muse, mutect2, varscan2
- ANKAR | c.1036del p.S346Qfs*59 | Frame Shift Del (DEL) | VAF 53/152 reads (35%) | catalogued as rs1372933355, COSV55618568; called by mutect2, pindel, varscan2
- ANKK1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 69/437 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs778503691, COSV100392904, COSV58273176; called by muse, mutect2, varscan2
- ANKRD13C | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 163/319 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201831251; called by muse, mutect2, varscan2
- ANKRD20A2P | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 157/924 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1297905824, COSV66464821; called by muse, mutect2, varscan2
- ANPEP | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 187/399 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs367926309; called by muse, mutect2, varscan2
- ANXA10 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs1183050946; called by muse, varscan2
- AOX1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 213/466 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65980156; called by muse, mutect2, varscan2
- APBB1IP | c.1799del p.P600Rfs*56 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as rs1314335534; called by mutect2, pindel, varscan2
- APLNR | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 242/519 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.102); catalogued as rs767575528, COSV57243099; called by muse, mutect2, varscan2
- APOA5 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 309/590 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs751198486, COSV57063783; called by muse, mutect2, varscan2
- APOB | c.13412C>T p.A4471V | Missense Mutation (SNP) | VAF 213/457 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs749549578, COSV99028730; called by muse, mutect2, varscan2
- ARHGAP20 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 178/349 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs776441588; called by muse, mutect2, varscan2
- ARHGAP45 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 216/478 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1355937003; called by muse, mutect2, varscan2
- ARHGEF12 | c.2491A>T p.I831F | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63105869; called by muse, mutect2, varscan2
- ARHGEF6 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 214/214 reads (100%) | catalogued as COSV51690566, COSV51694946; called by muse, mutect2, varscan2
- ARID1A | c.4388G>A p.R1463H | Missense Mutation (SNP) | VAF 204/438 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752827461, COSV61374560; called by muse, mutect2, varscan2
- ARID5B | c.2386del p.A797Lfs*6 | Frame Shift Del (DEL) | VAF 198/475 reads (42%) | catalogued as rs1044166801; called by mutect2, pindel, varscan2
- ARMC3 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 118/292 reads (40%) | catalogued as rs143785271; called by muse, mutect2, varscan2
- ARMC4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 189/404 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as rs142598573; called by muse, mutect2, varscan2
- ARRDC1 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 161/345 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs919158801; called by muse, mutect2, varscan2
- ARSI | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 205/441 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1175590084, COSV60816824; called by muse, mutect2, varscan2
- ARTN | c.251A>C p.Q84P (on ENST00000372354; = p.Q92P on NM_057090.2) | Missense Mutation (SNP) | VAF 219/405 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs969549945; called by muse, mutect2, varscan2
- ASCC3 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 227/459 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483972453, COSV64980973; called by muse, mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 150/379 reads (40%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ASMTL | c.1342A>G p.N448D | Missense Mutation (SNP) | VAF 50/661 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752631185; called by muse, mutect2
- ATIC | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 166/334 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs146882973; called by muse, mutect2, varscan2
- ATP10A | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 231/445 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63513754; called by muse, mutect2, varscan2
- ATP10D | c.2980C>T p.R994* | Nonsense Mutation (SNP) | VAF 192/378 reads (51%) | catalogued as rs200863114; called by muse, mutect2, varscan2
- ATP13A2 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 261/545 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs190323680; called by muse, mutect2, varscan2
- ATP1A1 | c.1640del p.G547Afs*7 | Frame Shift Del (DEL) | VAF 53/408 reads (13%) | catalogued as rs760784617; called by mutect2, pindel, varscan2
- ATP2B1 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 160/348 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666023; called by mutect2, varscan2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 196/391 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP4A | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 240/502 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1282429868, COSV99381931; called by muse, mutect2, varscan2
- ATR | c.3811T>C p.Y1271H | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.076); catalogued as rs1443828723; called by muse, mutect2, varscan2
- ATRNL1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs140372621; called by muse, mutect2, varscan2
- ATXN7 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 217/475 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1369874836, COSV55756867; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 150/328 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- AZIN2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 218/482 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs746470026, COSV53859536, COSV53859589; called by muse, mutect2, varscan2
- BAIAP2L2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 167/371 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs530602449; called by muse, mutect2, varscan2
- BCL2 | c.132del p.A45Hfs*51 | Frame Shift Del (DEL) | VAF 285/712 reads (40%) | catalogued as COSV61393940; called by mutect2, pindel, varscan2
- BCL2L12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 306/616 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372728241; called by muse, mutect2, varscan2
- BCORL1 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 259/260 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs758775339, COSV99500522; called by muse, mutect2, varscan2
- BCORL1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 276/277 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs187190724, COSV99499609; called by muse, mutect2, varscan2
- BEND5 | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 28/391 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs193921115, COSV65716788; ClinVar: uncertain significance; called by muse, mutect2
- BICRA | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749047335; called by muse, mutect2, varscan2
- BMP1 | c.2471G>A p.S824N | Missense Mutation (SNP) | VAF 231/465 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs1373798293, COSV100114774; called by muse, mutect2, varscan2
- BMP8A | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); catalogued as rs1426657769; called by muse, mutect2
- BNIP2 | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 126/254 reads (50%) | catalogued as COSV99985662; called by muse, mutect2, varscan2
- BNIPL | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.754); catalogued as rs757436813; called by muse, varscan2
- BRD4 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 202/397 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs777966382, COSV54584920; called by muse, mutect2, varscan2
- BTBD6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 222/461 reads (48%) | catalogued as rs749575989; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 208/408 reads (51%) | catalogued as rs752512017; called by mutect2, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 105/232 reads (45%) | catalogued as rs1558005082; called by mutect2, varscan2
- BTNL2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs769178206, COSV100896036; called by muse, mutect2, varscan2
- C16orf54 | c.486del p.A163Pfs*5 | Frame Shift Del (DEL) | VAF 274/680 reads (40%) | catalogued as rs779355314; called by mutect2, pindel, varscan2
- C1orf174 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 166/339 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV64366181; called by muse, mutect2, varscan2
- C22orf31 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 208/473 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs772347124, COSV53310669; called by muse, mutect2, varscan2
- C3orf80 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 289/527 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.856); catalogued as rs1018775441; called by muse, mutect2, varscan2
- C5 | c.4201C>T p.R1401C | Missense Mutation (SNP) | VAF 162/331 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs145968939; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 141/354 reads (40%) | catalogued as rs372345940; called by mutect2, varscan2
- C8orf34 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 173/358 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs190887237; called by muse, mutect2, varscan2
- CA11 | c.916del p.R306Gfs*51 | Frame Shift Del (DEL) | VAF 246/570 reads (43%) | catalogued as COSV50033830; called by mutect2, pindel, varscan2
- CABIN1 | c.4784C>T p.P1595L | Missense Mutation (SNP) | VAF 241/481 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV54078643; called by muse, mutect2, varscan2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 205/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, varscan2
- CACNA1D | c.6070T>G p.W2024G (on ENST00000350061 / NM_001128840.3; = p.W2044G on NM_000720.4) | Missense Mutation (SNP) | VAF 269/535 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV99860849; called by muse, mutect2, varscan2
- CACNA1E | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 298/574 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as rs374689888, COSV62395329; called by muse, mutect2, varscan2
- CACNA1H | c.6503C>T p.A2168V | Missense Mutation (SNP) | VAF 240/514 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs765008315; called by muse, mutect2, varscan2
- CACNG6 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 328/564 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs746712453; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 263/669 reads (39%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CACNG7 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 187/395 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs369839062, COSV99712202; called by muse, mutect2, varscan2
- CACTIN | c.1819_1821del p.F607del | In Frame Del (DEL) | VAF 177/414 reads (43%) | catalogued as rs751667810; called by pindel, varscan2
- CADPS | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs751422032; called by muse, mutect2, varscan2
- CADPS2 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs1476363833; called by muse, mutect2
- CALD1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 203/451 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1267886086, COSV62649429, COSV62650905; called by muse, mutect2, varscan2
- CAMK2D | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 67/220 reads (30%) | catalogued as rs778447492, COSV99594889; called by muse, mutect2, varscan2
- CAMSAP2 | c.1370G>A p.R457Q (on ENST00000236925 / NM_001297707.2; = p.R446Q on NM_203459.3) | Missense Mutation (SNP) | VAF 129/239 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); catalogued as rs146524997, COSV52668223; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 154/318 reads (48%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA1 | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 208/390 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as rs770924661; called by muse, mutect2, varscan2
- CAPN7 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 127/268 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99512517; called by muse, mutect2, varscan2
- CARD8 | c.1085C>T p.S362L (on ENST00000651546 / NM_001184900.3; = p.S312L on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764264265; called by muse, mutect2, varscan2
- CARMIL1 | c.1829_1831del p.N610del | In Frame Del (DEL) | VAF 77/229 reads (34%) | catalogued as rs764270535; called by pindel, varscan2
- CARMIL2 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 269/555 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs749823173; called by muse, mutect2, varscan2
- CARMIL3 | c.3103G>A p.V1035M | Missense Mutation (SNP) | VAF 195/432 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs542450759; called by muse, mutect2, varscan2
- CASP8 | c.1068del p.F356Lfs*26 (on ENST00000432109 / NM_033355.3; = p.F373Lfs*26 on NM_001228.4) | Frame Shift Del (DEL) | VAF 156/367 reads (43%) | catalogued as COSV51847031; called by mutect2, pindel, varscan2
- CATSPER1 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 140/278 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764683817, COSV56412480; called by muse, varscan2
- CAV1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 193/397 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs143730366; called by muse, mutect2, varscan2
- CAVIN2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 251/477 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs762124159, COSV58423626; called by muse, mutect2, varscan2
- CBX2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 102/522 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs782145802, COSV53968469; called by muse, mutect2, varscan2
- CC2D1A | c.2693del p.G898Vfs*45 | Frame Shift Del (DEL) | VAF 153/393 reads (39%) | catalogued as rs1423002835; called by mutect2, pindel, varscan2
- CCBE1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 203/422 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs115982879, COSV67949322; called by muse, mutect2, varscan2
- CCDC116 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 169/351 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs1166702926; called by muse, mutect2, varscan2
- CCDC12 | c.401C>T p.A134V (on ENST00000425441 / NM_001277074.1; = p.A147V on NM_144716.5) | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52765364; called by muse, mutect2, varscan2
- CCDC127 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 198/397 reads (50%) | catalogued as rs1204741024; called by muse, varscan2
- CCDC137 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 262/566 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1286033386; called by muse, varscan2
- CCDC168 | c.16334C>T p.T5445M | Missense Mutation (SNP) | VAF 215/422 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs144201982, COSV100487667; called by muse, mutect2, varscan2
- CCDC168 | c.323del p.L108* | Frame Shift Del (DEL) | VAF 75/186 reads (40%) | catalogued as rs34318963; called by mutect2, pindel, varscan2
- CCDC17 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 173/386 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs749435522, COSV59647674; called by muse, mutect2, varscan2
- CCDC185 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 252/514 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs765942457; called by muse, varscan2
- CCDC40 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 151/332 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1052358414, COSV66473301; called by muse, varscan2
- CCDC57 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 197/426 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs369435465; called by muse, mutect2, varscan2
- CCDC77 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 187/403 reads (46%) | catalogued as rs762749495; called by muse, mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 152/329 reads (46%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCDC80 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 201/415 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs565610574, COSV52820247; called by muse, mutect2, varscan2
- CD200R1 | c.161C>A p.A54D (on ENST00000471858 / NM_170780.3; = p.A77D on NM_138806.4) | Missense Mutation (SNP) | VAF 151/348 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55603254; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 192/388 reads (49%) | catalogued as rs760923345; called by mutect2, varscan2
- CDAN1 | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 170/359 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.194); catalogued as rs373357147; called by muse, mutect2, varscan2
- CDC42BPA | c.3004G>A p.G1002S (on ENST00000334218 / NM_001366019.2; = p.G989S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/233 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99043556; called by muse, mutect2, varscan2
- CDCA3 | c.257del p.P86Qfs*5 | Frame Shift Del (DEL) | VAF 96/278 reads (35%) | catalogued as rs782448572; called by mutect2, pindel, varscan2
- CDCA4 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 272/526 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs549418658, COSV60314955; called by muse, mutect2, varscan2
- CDCP1 | c.1840del p.R614Gfs*38 | Frame Shift Del (DEL) | VAF 189/513 reads (37%) | catalogued as COSV56104487; called by mutect2, pindel, varscan2
- CDH18 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1409678142, COSV99937796; called by muse, mutect2, varscan2
- CDH19 | c.1233C>A p.S411R | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as rs1340973556; called by muse, mutect2
- CDH9 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.196); catalogued as rs1265659383; called by muse, mutect2, varscan2
- CDHR5 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 181/325 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV62764042; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 233/496 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by muse, mutect2, varscan2
- CEMIP | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 180/383 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as rs759087523; called by muse, mutect2, varscan2
- CENPJ | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs369635681, COSV67883116, COSV67883522; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 84/153 reads (55%) | catalogued as rs769310263; called by mutect2, varscan2
- CEP131 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 199/403 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359607113; called by muse, mutect2, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 182/479 reads (38%) | catalogued as rs1431118175; called by mutect2, pindel, varscan2
- CEP192 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV58060666; called by muse, mutect2
- CEP250 | c.7127G>A p.R2376H | Missense Mutation (SNP) | VAF 176/406 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs374274791, COSV61168872, COSV61170900; called by muse, varscan2
- CEP295 | c.4309A>G p.T1437A | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1466451928; called by muse, mutect2, varscan2
- CEP295 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1212253453, COSV57349551; called by muse, varscan2
- CEP76 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs755171008; called by muse, mutect2, varscan2
- CEP97 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 211/395 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374438407; called by muse, mutect2, varscan2
- CES2 | c.816G>A p.T272= | Splice Region (SNP) | VAF 26/284 reads (9%) | catalogued as rs142953579, COSV100399449; called by muse, mutect2
- CFAP410 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 186/415 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1251364740; called by muse, mutect2
- CFAP44 | c.3423del p.E1142Nfs*35 | Frame Shift Del (DEL) | VAF 110/304 reads (36%) | catalogued as rs947129972; called by pindel, varscan2
- CFAP46 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 152/372 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1180604344; called by muse, mutect2
- CFHR3 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 179/408 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs1238197794; called by muse, mutect2, varscan2
- CGAS | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 121/237 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149902826, COSV100943685; called by muse, varscan2
- CHD7 | c.3745C>T p.R1249W | Missense Mutation (SNP) | VAF 170/371 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050617514; called by muse, mutect2, varscan2
- CHD8 | c.7496C>A p.P2499H (on ENST00000646647 / NM_001170629.2; = p.P2220H on NM_020920.4) | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1212151127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.6866C>T p.A2289V | Missense Mutation (SNP) | VAF 190/396 reads (48%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.788); catalogued as rs1338867336; called by muse, mutect2, varscan2
- CHP2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 208/414 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as rs758157005; called by muse, mutect2, varscan2
- CHRNA3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 210/450 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775325162, COSV100468651, COSV58775586; called by muse, mutect2
- CHRNB4 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 236/481 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199844639, COSV99929417; called by muse, varscan2
- CHST13 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 269/537 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1231021325, COSV60043121; called by muse, mutect2, varscan2
- CHTF18 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 184/377 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746734598; called by muse, mutect2, varscan2
- CIAO3 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 261/531 reads (49%) | catalogued as rs575691401, COSV52405327; called by muse, varscan2
- CIITA | c.1812_1814del p.L605del | In Frame Del (DEL) | VAF 183/392 reads (47%) | catalogued as rs1432967208; called by pindel, varscan2
- CIT | c.4843G>A p.A1615T | Missense Mutation (SNP) | VAF 152/366 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.812); catalogued as rs749790889, COSV55859586; called by muse, mutect2, varscan2
- CIZ1 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs760065353, COSV99477255; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 89/186 reads (48%) | catalogued as rs752250702; called by mutect2, varscan2
- CKB | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 251/470 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs773350958; called by muse, mutect2, varscan2
- CLEC4D | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 150/341 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs139845503; called by muse, mutect2, varscan2
- CLGN | c.822dup p.P275Tfs*2 | Frame Shift Ins (INS) | VAF 166/399 reads (42%) | catalogued as rs1442881852; called by mutect2, pindel, varscan2
- CLIC6 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 240/516 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs996635682, COSV100659314; called by muse, varscan2
- CLRN3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 175/364 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs371220164; called by muse, mutect2, varscan2
- CLSPN | c.3565C>T p.Q1189* | Nonsense Mutation (SNP) | VAF 62/137 reads (45%) | catalogued as rs1339597031, COSV52050017; called by muse, mutect2, varscan2
- CLUH | c.92C>T p.P31L (on ENST00000435359; = p.P69L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/491 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs758323365; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 136/272 reads (50%) | catalogued as rs758676375; called by mutect2, varscan2
- COL11A1 | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614689; called by muse, mutect2, varscan2
- COL13A1 | c.1550del p.P517Qfs*9 (on ENST00000398978 / NM_001130103.2; = p.P460Qfs*9 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 225/558 reads (40%) | catalogued as rs770933186, COSV100637433; called by mutect2, pindel, varscan2
- COL14A1 | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs146557532, COSV52870688; called by muse, mutect2, varscan2
- COL14A1 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs781191822, COSV52848407; called by muse, mutect2, varscan2
- COL15A1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 263/455 reads (58%) | SIFT tolerated (0.98); PolyPhen benign (0.057); catalogued as rs570016118, COSV66642410; called by muse, mutect2, varscan2
- COL1A1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as CM137813; called by mutect2, varscan2
- COL22A1 | c.2386C>T p.R796* | Nonsense Mutation (SNP) | VAF 117/358 reads (33%) | catalogued as rs373752145, COSV100281308; called by muse, mutect2, varscan2
- COL28A1 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 151/342 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68084205; called by muse, mutect2, varscan2
- COL3A1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 154/313 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485092842, COSV100483994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A3 | c.2843C>T p.S948F | Missense Mutation (SNP) | VAF 170/336 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs927872112, COSV59258281; called by muse, mutect2, varscan2
- COL4A6 | c.3884G>A p.G1295D | Missense Mutation (SNP) | VAF 125/360 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57864381; called by muse, varscan2
- COL5A3 | c.4525G>A p.V1509M | Missense Mutation (SNP) | VAF 286/529 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1329233852; called by muse, mutect2, varscan2
- COL5A3 | c.3560G>C p.G1187A | Missense Mutation (SNP) | VAF 186/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1228070058; called by muse, mutect2
- COL6A3 | c.8047G>A p.V2683M | Missense Mutation (SNP) | VAF 246/462 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037630319; called by muse, mutect2, varscan2
- COL6A3 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs374447921, COSV99799860; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A5 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.759); catalogued as rs146510478; called by muse, mutect2
- COL6A6 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 21/579 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62039583; called by muse, mutect2
- COL8A1 | c.1631del p.P544Qfs*30 | Frame Shift Del (DEL) | VAF 226/556 reads (41%) | catalogued as COSV53736505; called by mutect2, pindel, varscan2
- COL8A1 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 37/537 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as rs1243559178, COSV53729532; called by muse, mutect2
- CORO6 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 187/378 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375611970; called by muse, mutect2, varscan2
- CPED1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 138/275 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60004265; called by muse, mutect2, varscan2
- CPN1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 231/433 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753854211; called by muse, mutect2, varscan2
- CPQ | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as rs776801209; called by muse, mutect2, varscan2
- CPSF1 | c.3821G>A p.R1274H | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs781806525, COSV58232740; called by muse, mutect2
- CPSF7 | c.806del p.P269Hfs*43 (on ENST00000394888 / NM_001136040.4; = p.P312Hfs*43 on NM_024811.4) | Frame Shift Del (DEL) | VAF 257/615 reads (42%) | catalogued as rs1429447472; called by mutect2, pindel, varscan2
- CREBBP | c.7162G>A p.A2388T | Missense Mutation (SNP) | VAF 246/510 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs756011865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 270/525 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114474; called by muse, mutect2, varscan2
- CREM | c.860G>A p.R287H (on ENST00000429130; = p.R242H on NM_181571.3) | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs936104894, COSV100415437; called by muse, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 270/652 reads (41%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSMD1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 224/433 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs374230800; called by muse, mutect2, varscan2
- CT47B1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 86/125 reads (69%) | catalogued as rs1339926372; called by muse, mutect2, varscan2
- CTDP1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 206/404 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1028353134, COSV99310889; called by muse, mutect2, varscan2
- CTRB2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as rs1235720810; called by muse, mutect2, varscan2
- CTSV | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 156/296 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52344574; called by muse, mutect2, varscan2
- CUL3 | c.1358del p.N453Tfs*2 | Frame Shift Del (DEL) | VAF 79/213 reads (37%) | catalogued as rs1366667901; called by mutect2, pindel, varscan2
- CWC25 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305852779; called by muse, mutect2, varscan2
- CYB5D2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 173/332 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1197999512, COSV56802064; called by muse, mutect2, varscan2
- CYLC2 | c.747del p.D250Mfs*106 | Frame Shift Del (DEL) | VAF 184/387 reads (48%) | catalogued as COSV100872458; called by mutect2, varscan2
- CYP11B1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 205/499 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158616210; called by muse, mutect2, varscan2
- CYP21A2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 124/563 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs72552757, CM022200; called by muse, mutect2, varscan2
- CYP26C1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 327/579 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs746340948; called by muse, mutect2, varscan2
- CYP4F22 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs561480298, COSV54106195; called by muse, mutect2, varscan2
- CYREN | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs776124276, COSV51966094; called by muse, mutect2, varscan2
- DAAM2 | c.2698C>T p.R900C (on ENST00000274867 / NM_001201427.2; = p.R899C on NM_015345.3) | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1047541318, COSV51313148; called by muse, mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 198/269 reads (74%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAPK1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs1320849258, COSV63787613; called by muse, mutect2, varscan2
- DAPK3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 272/556 reads (49%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1190048528, COSV56663236; called by muse, mutect2, varscan2
- DBX1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 154/282 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57053677; called by muse, mutect2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 206/406 reads (51%) | catalogued as rs782606429; called by mutect2, varscan2
- DCC | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 217/448 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as COSV101472307; called by muse, mutect2, varscan2
- DCDC1 | c.4396C>T p.R1466C (on ENST00000597505 / NM_001367979.1; = p.R573C on NM_020869.3) | Missense Mutation (SNP) | VAF 175/352 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761430464, COSV100337933, COSV100338441, COSV57998997; called by muse, mutect2, varscan2
- DCSTAMP | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 170/328 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs749718466; called by muse, mutect2, varscan2
- DDX47 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61911459; called by muse, mutect2, varscan2
- DDX50 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 95/200 reads (48%) | catalogued as rs142295291; called by muse, mutect2, varscan2
- DDX58 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 132/290 reads (46%) | catalogued as rs773422076, COSV65883152; called by muse, mutect2, varscan2
- DENND2B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 229/465 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142799946, COSV58201975; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 117/279 reads (42%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 106/262 reads (40%) | catalogued as rs35538077; called by mutect2, varscan2
- DICER1 | c.3308A>T p.D1103V | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1566769521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIP2A | c.2875del p.V959Lfs*49 | Frame Shift Del (DEL) | VAF 121/310 reads (39%) | catalogued as COSV59477609; called by mutect2, pindel, varscan2
- DIP2B | c.732dup p.S245Lfs*5 | Frame Shift Ins (INS) | VAF 217/514 reads (42%) | catalogued as rs1270852059; called by mutect2, pindel, varscan2
- DISP3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 229/427 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186903277, COSV53819377; called by muse, mutect2, varscan2
- DLG1 | c.2098G>A p.V700I (on ENST00000419354 / NM_001290983.1; = p.V722I on NM_004087.2) | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs556519100; called by muse, mutect2, varscan2
- DLGAP1 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 224/472 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192982479; called by muse, mutect2, varscan2
- DLX4 | c.340G>A p.A114T (on ENST00000240306 / NM_138281.3; = p.A42T on NM_001934.3) | Missense Mutation (SNP) | VAF 279/596 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs780722446; called by muse, varscan2
- DMRTC2 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 76/507 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99523279; called by muse, mutect2, varscan2
- DMRTC2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782073409, COSV99523260; called by muse, mutect2, varscan2
- DMWD | c.185del p.P62Rfs*149 | Frame Shift Del (DEL) | VAF 248/639 reads (39%) | catalogued as rs1384560335; called by mutect2, pindel, varscan2
- DMXL1 | c.7706G>A p.R2569H | Missense Mutation (SNP) | VAF 176/405 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750990275, COSV60704181; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 172/399 reads (43%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 64/165 reads (39%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.13181C>T p.A4394V | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs564517631; called by muse, varscan2
- DNAH17 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs199854936, COSV101101931; called by muse, mutect2, varscan2
- DNAH17 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs188562373; called by muse, mutect2, varscan2
- DNAH2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 192/388 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50020974; called by muse, mutect2, varscan2
- DNAH2 | c.7147G>A p.A2383T | Missense Mutation (SNP) | VAF 91/185 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs760670678, COSV66724474; called by muse, mutect2, varscan2
- DNAH3 | c.11875G>A p.G3959R | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99769043; called by muse, mutect2, varscan2
- DNAJA2 | c.204A>T p.R68S | Missense Mutation (SNP) | VAF 167/342 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1197667183; called by muse, mutect2, varscan2
- DNAJB14 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 214/441 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV62036464; called by muse, mutect2, varscan2
- DNAJC22 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs200327446, COSV101222508; called by muse, mutect2, varscan2
- DNASE1 | c.25del p.A9Rfs*15 | Frame Shift Del (DEL) | VAF 186/471 reads (39%) | catalogued as rs746491054; called by mutect2, pindel, varscan2
- DOCK10 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 141/283 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs760214174; called by muse, mutect2, varscan2
- DPP4 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 198/383 reads (52%) | catalogued as rs745777648, COSV62106316; called by muse, mutect2, varscan2
- DPP6 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs892507991; called by muse, mutect2, varscan2
- DPYS | c.35del p.G12Vfs*86 | Frame Shift Del (DEL) | VAF 250/592 reads (42%) | catalogued as rs1212167138; called by mutect2, pindel, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 212/446 reads (48%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2, varscan2
- DTWD1 | c.503del p.N168Mfs*22 | Frame Shift Del (DEL) | VAF 177/515 reads (34%) | catalogued as rs1412686031; called by pindel, varscan2
- DUOX1 | c.3503C>T p.P1168L | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58478395; called by muse, mutect2, varscan2
- DUSP8 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 252/483 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs766200658; called by muse, mutect2, varscan2
- DVL3 | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 23/738 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.121); catalogued as rs1489880646; called by muse, mutect2
- DYNC2I1 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1297205333; called by muse, varscan2
- E2F1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs183250565, COSV99864845; called by muse, mutect2, varscan2
- ECE1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 266/609 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.586); catalogued as rs1049897620; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1237C>T p.R413* (on ENST00000361735 / NM_015935.5; = p.R327* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 149/294 reads (51%) | catalogued as rs963906263; called by muse, mutect2, varscan2
- EFCAB6 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV53069566; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 139/363 reads (38%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EGFR | c.2839A>G p.M947V | Missense Mutation (SNP) | VAF 115/257 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368698152; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 246/644 reads (38%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF3A | c.795del p.K265Nfs*7 | Frame Shift Del (DEL) | VAF 129/338 reads (38%) | catalogued as rs34481774; called by mutect2, pindel, varscan2
- EIF3A | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64963353, COSV64963460; called by muse, mutect2, varscan2
- EIF3C | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 239/963 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374480438, COSV59059672; called by muse, mutect2, varscan2
- EIF4A1 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1283063684; called by muse, mutect2, varscan2
- ELFN2 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 220/462 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV68744093; called by muse, mutect2, varscan2
- ELP5 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 177/400 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV59708561; called by muse, mutect2, varscan2
- ENG | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 220/429 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs757113987; called by muse, mutect2, varscan2
- ENTPD8 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 152/344 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs578205858, COSV58161914; called by muse, mutect2, varscan2
- EP400 | c.7139G>A p.R2380H | Missense Mutation (SNP) | VAF 226/438 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1395587120, COSV57770513; called by muse, mutect2, varscan2
- EPB41L3 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs769159490, COSV59461373; called by muse, mutect2, varscan2
- EPHA10 | c.650del p.G217Afs*132 (on ENST00000373048 / NM_001099439.2; = p.G217Afs*82 on NM_173641.2) | Frame Shift Del (DEL) | VAF 238/591 reads (40%) | catalogued as COSV57624618; called by mutect2, pindel, varscan2
- EPM2A | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62296224; called by muse, mutect2, varscan2
- EPS8L3 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as rs746842011, COSV62609143; called by muse, mutect2, varscan2
- EPX | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 159/326 reads (49%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.931); catalogued as rs144998259; called by muse, mutect2, varscan2
- ERBB3 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 240/494 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247893, COSV57261351; called by muse, mutect2, varscan2
- ERFE | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 205/401 reads (51%) | SIFT deleterious, low confidence (0); catalogued as rs772260697; called by muse, mutect2, varscan2
- ERFL | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 226/448 reads (50%) | SIFT tolerated, low confidence (0.07); catalogued as rs992568720; called by muse, mutect2, varscan2
- ERGIC2 | c.25del p.T9Lfs*2 | Frame Shift Del (DEL) | VAF 114/296 reads (39%) | catalogued as rs1370236096; called by mutect2, pindel, varscan2
- ERICH4 | c.64dup p.Q22Pfs*29 | Frame Shift Ins (INS) | VAF 150/358 reads (42%) | catalogued as rs567420399; called by mutect2, varscan2
- ERVFRD-1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs768463887, COSV65369528; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1103A>G p.D368G | Missense Mutation (SNP) | VAF 145/318 reads (46%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV66920735; called by muse, mutect2, varscan2
- EVC2 | c.3151G>A p.V1051M | Missense Mutation (SNP) | VAF 322/628 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs775917298; called by muse, mutect2, varscan2
- EVX1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 200/404 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs867878464; called by muse, mutect2, varscan2
- EXOC6B | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 155/303 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as rs766170220, COSV55566619, COSV99723156; called by muse, mutect2, varscan2
- EYA1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 178/388 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.882); catalogued as rs181191349; ClinVar: benign; called by muse, mutect2, varscan2
- F10 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs751623132, COSV65021899; called by muse, mutect2, varscan2
- FAM117B | c.1144dup p.L382Pfs*6 | Frame Shift Ins (INS) | VAF 150/322 reads (47%) | catalogued as rs761783143; called by mutect2, varscan2
- FAM131A | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 282/525 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs759559677; called by muse, mutect2, varscan2
- FAM186A | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs1295246269; called by muse, mutect2, varscan2
- FAM20C | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 263/570 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1437202079; called by muse, mutect2, varscan2
- FAM221B | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1013222665, COSV52414614; called by muse, mutect2, varscan2
- FAM221B | c.62del p.P21Lfs*20 | Frame Shift Del (DEL) | VAF 183/466 reads (39%) | catalogued as rs1323115063, COSV65073645, COSV65075016; called by mutect2, pindel, varscan2
- FAM71C | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 173/368 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs760259280; called by muse, mutect2, varscan2
- FAM89A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767532073, COSV100792581; called by muse, mutect2, varscan2
- FAN1 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 207/404 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1452542279; called by muse, mutect2, varscan2
- FASTKD5 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 143/327 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs772486694, COSV99418845; called by muse, mutect2, varscan2
- FAT2 | c.11533C>T p.R3845C | Missense Mutation (SNP) | VAF 202/413 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as rs762295424; called by muse, mutect2, varscan2
- FBN1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 150/311 reads (48%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.959); catalogued as rs749989129, COSV57313314; called by muse, mutect2, varscan2
- FBXL22 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 160/309 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758363206; called by muse, mutect2, varscan2
- FCRL2 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 187/347 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV63832525; called by muse, mutect2, varscan2
- FCSK | c.3043del p.H1015Tfs*19 | Frame Shift Del (DEL) | VAF 252/603 reads (42%) | catalogued as rs754711319; called by mutect2, pindel, varscan2
- FER1L6 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 185/366 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67548321; called by muse, mutect2, varscan2
- FEZF1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 171/349 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV58659765; called by muse, mutect2, varscan2
- FEZF2 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 319/649 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as COSV99032474; called by muse, mutect2, varscan2
- FGB | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs775243595; called by muse, mutect2, varscan2
- FGD5 | c.3095C>T p.A1032V | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758570732, COSV53240556; called by muse, mutect2, varscan2
- FGF11 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53440373; called by muse, mutect2, varscan2
- FGF2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 241/501 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52648902; called by muse, mutect2, varscan2
- FGF3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 294/562 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1156753470, COSV61926245; called by muse, mutect2, varscan2
- FHOD3 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99068633; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 230/507 reads (45%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGLA | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 300/610 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60089432; called by muse, mutect2, varscan2
- FKRP | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 174/414 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1450841129, CM013809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV57956871; called by muse, mutect2, varscan2
- FLNC | c.2888del p.P963Rfs*26 | Frame Shift Del (DEL) | VAF 215/491 reads (44%) | catalogued as rs764460165; called by mutect2, pindel, varscan2
- FMNL1 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs752976420; called by muse, mutect2, varscan2
- FMO4 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs1374387779; called by muse, mutect2
- FNDC10 | c.290del p.P97Rfs*91 | Frame Shift Del (DEL) | VAF 81/330 reads (25%) | catalogued as rs1334264965; called by mutect2, pindel, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 169/374 reads (45%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXD3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 25/618 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1364492012; called by muse, mutect2
- FOXP1 | c.1768A>G p.M590V | Missense Mutation (SNP) | VAF 184/389 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201446635; called by muse, mutect2, varscan2
- FOXP1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59541468; called by muse, mutect2, varscan2
- FOXP2 | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs768186362, COSV100646084; called by muse, mutect2, varscan2
- FOXQ1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 323/651 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs996666315; called by muse, mutect2, varscan2
- FOXRED1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 145/272 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs150427279; called by muse, mutect2, varscan2
- FRMD3 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 114/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435490016, COSV58461025; called by muse, mutect2, varscan2
- FRMD4A | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 180/369 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs772563228, COSV52717882; called by muse, mutect2, varscan2
- FSCN2 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 32/657 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603335; called by muse, mutect2
- FTHL17 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs756401411; called by muse, mutect2, varscan2
- FTSJ3 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs749821889; called by muse, mutect2, varscan2
- FUT4 | c.741del p.D248Tfs*48 | Frame Shift Del (DEL) | VAF 650/916 reads (71%) | catalogued as rs746338726; called by mutect2, pindel, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 142/338 reads (42%) | catalogued as rs765036679; called by mutect2, varscan2
- GABRQ | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.781); catalogued as rs782073807, COSV64783672; called by muse, mutect2, varscan2
- GAL3ST3 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1253031284; called by muse, varscan2
- GALNS | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs372585484; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 238/552 reads (43%) | catalogued as rs1553309006; called by mutect2, pindel, varscan2
- GALT | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 200/439 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM074211; called by muse, mutect2, varscan2
- GAS6 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 204/458 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as rs202234400; called by muse, mutect2
- GATA5 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 227/489 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556876322; called by muse, mutect2, varscan2
- GBP3 | c.639del p.D214Ifs*51 | Frame Shift Del (DEL) | VAF 95/258 reads (37%) | catalogued as rs1557727607; called by mutect2, pindel, varscan2
- GCAT | c.818del p.X273_splice | Splice Site (DEL) | VAF 142/332 reads (43%) | catalogued as rs1569083487; called by mutect2, pindel, varscan2
- GCKR | c.323del p.G108Afs*17 | Frame Shift Del (DEL) | VAF 208/541 reads (38%) | catalogued as COSV99253866; called by mutect2, pindel, varscan2
- GCN1 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 238/439 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs575068347; called by muse, mutect2, varscan2
- GDF1 | c.933del p.P312Rfs*73 | Frame Shift Del (DEL) | VAF 180/469 reads (38%) | catalogued as rs1213194580; called by mutect2, pindel, varscan2
- GDF10 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 276/559 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1555206775; called by muse, mutect2, varscan2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 96/251 reads (38%) | catalogued as rs755972268; called by mutect2, pindel, varscan2
- GGH | c.825dup p.V276Cfs*2 | Frame Shift Ins (INS) | VAF 131/323 reads (41%) | catalogued as rs747800974; called by mutect2, pindel, varscan2
- GJA3 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 252/522 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs981126461, CM102458, COSV53835798; called by muse, mutect2, varscan2
- GJD2 | c.362del p.P121Lfs*4 | Frame Shift Del (DEL) | VAF 265/614 reads (43%) | catalogued as rs748483263, COSV51749500; called by mutect2, pindel, varscan2
- GLI3 | c.3437T>A p.L1146H | Missense Mutation (SNP) | VAF 331/644 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV67888048; called by muse, mutect2, varscan2
- GLIS3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 37/731 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1411066331; called by muse, mutect2
- GLRA1 | c.1106G>T p.R369L (on ENST00000455880 / NM_001146040.2; = p.R361L on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs147471585, COSV51027148; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 120/266 reads (45%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAS | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 194/449 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs763257494, COSV100005849; called by muse, mutect2, varscan2
- GNPTAB | c.2869A>G p.M957V | Missense Mutation (SNP) | VAF 167/368 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755493862; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 141/284 reads (50%) | catalogued as rs763679060; called by mutect2, varscan2
- GPC5 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 156/362 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1182917560, COSV65605985; called by muse, mutect2, varscan2
- GPC5 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 207/450 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1248980010; called by muse, mutect2, varscan2
- GPR15 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52520464; called by muse, mutect2, varscan2
- GPR63 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 169/365 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs185129489; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 221/536 reads (41%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GPT | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 217/472 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747432300; called by muse, mutect2, varscan2
- GPT | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 173/354 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs773993974, COSV52953715; called by muse, varscan2
- GRAMD1B | c.1530del p.L511* | Frame Shift Del (DEL) | VAF 160/405 reads (40%) | catalogued as COSV99074528; called by mutect2, pindel, varscan2
- GRB10 | c.1381G>A p.A461T (on ENST00000398812; = p.A415T on NM_001001549.3) | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV60015419; called by muse, mutect2, varscan2
- GREB1L | c.4507C>T p.R1503W | Missense Mutation (SNP) | VAF 197/347 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52551588; called by muse, mutect2, varscan2
- GREM2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 181/433 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs758912690, COSV58953843; called by muse, mutect2, varscan2
- GRIK1 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 198/389 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58711884; called by muse, mutect2, varscan2
- GRIN3B | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 18/459 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1352525326; called by muse, mutect2
- GRK1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200986774; called by muse, mutect2, varscan2
- GRM3 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 189/452 reads (42%) | catalogued as COSV64466766; called by muse, mutect2, varscan2
- GRM6 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 247/509 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51431979; called by muse, mutect2, varscan2
- GSDME | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 178/346 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs377050475; called by muse, varscan2
- GTF2IRD1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 182/364 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782299708; called by muse, mutect2, varscan2
- GTF3C1 | c.3864G>T p.K1288N | Missense Mutation (SNP) | VAF 137/295 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV62243229; called by muse, mutect2, varscan2
- GUCY1A1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 156/325 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143862431; called by muse, mutect2, varscan2
- GUCY1A2 | c.1205A>T p.K402M | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56490301; called by muse, mutect2, varscan2
- GYPC | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs768335450; called by muse, mutect2, varscan2
- H2AC1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 145/282 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.51); catalogued as rs1312427918, COSV51236711; called by muse, mutect2, varscan2
- H2BC9 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 179/417 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as rs1379428825; called by muse, mutect2, varscan2
- HAP1 | c.1457C>T p.T486M (on ENST00000310778 / NM_001367460.1; = p.T434M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/336 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs782546957, COSV57880158; called by muse, mutect2, varscan2
- HDAC6 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61927740; called by muse, mutect2, varscan2
- HDGFL2 | c.373del p.V125Sfs*7 | Frame Shift Del (DEL) | VAF 206/591 reads (35%) | catalogued as rs914269467; called by pindel, varscan2
- HECW2 | c.4379A>T p.D1460V | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646235; called by muse, mutect2
- HEMGN | c.322del p.T108Lfs*7 | Frame Shift Del (DEL) | VAF 209/506 reads (41%) | catalogued as rs751768399; called by mutect2, pindel, varscan2
- HERC1 | c.7832del p.G2611Afs*37 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | catalogued as rs1159378962, COSV71247711; called by pindel, varscan2
- HERC2 | c.13708G>A p.A4570T | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as rs1350012976; called by muse, mutect2, varscan2
- HEY1 | c.143del p.L48Wfs*9 | Frame Shift Del (DEL) | VAF 180/418 reads (43%) | catalogued as rs745485637; called by mutect2, pindel, varscan2
- HHIPL1 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 28/664 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs1485645685; called by muse, mutect2
- HIC1 | c.1801G>A p.A601T (on ENST00000322941 / NM_001098202.1; = p.A582T on NM_006497.4) | Missense Mutation (SNP) | VAF 234/456 reads (51%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.979); catalogued as COSV53963219; called by muse, varscan2
- HIF1A | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100049385; called by muse, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 226/348 reads (65%) | catalogued as rs199474609; called by mutect2, varscan2
- HOXA7 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 247/478 reads (52%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.028); catalogued as rs565645084; called by muse, mutect2, varscan2
- HOXB1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 259/477 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs750258334; called by muse, mutect2, varscan2
- HOXB9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 337/680 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60817571; called by muse, mutect2, varscan2
- HRH2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 201/374 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs367866082; called by muse, mutect2, varscan2
- HRH3 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 191/325 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as rs1156906048, COSV58051039; called by muse, mutect2, varscan2
- HSF4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99263561; called by muse, mutect2, varscan2
- HSPH1 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 149/368 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765918581, COSV60710697; called by muse, mutect2, varscan2
- HYAL4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 202/422 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758644949; called by muse, mutect2, varscan2
- IDE | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747993929, COSV56424941; called by muse, mutect2, varscan2
- IFIH1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs186942719, COSV55125491; called by muse, mutect2, varscan2
- IFNGR1 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV62989434; called by muse, mutect2, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 204/507 reads (40%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IGDCC3 | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 175/350 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.227); catalogued as rs1382698847; called by muse, mutect2, varscan2
- IGF1R | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 147/314 reads (47%) | catalogued as COSV51286903; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 156/302 reads (52%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 304/619 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.592); catalogued as rs1195568130; called by muse, varscan2
- IGFBP1 | c.268del p.E90Sfs*40 | Frame Shift Del (DEL) | VAF 260/708 reads (37%) | catalogued as rs747136225; called by pindel, varscan2
- IGFBP3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 280/568 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1419444305; called by muse, mutect2
- IGFLR1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1262642786, COSV53075805; called by muse, mutect2
- IGHG1 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 201/462 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1474544394; called by muse, mutect2, varscan2
- IGHV3-20 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 211/460 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs372438612; called by muse, mutect2, varscan2
- IGSF3 | c.2414G>A p.R805H (on ENST00000369486 / NM_001007237.3; = p.R825H on NM_001542.4) | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.919); catalogued as rs1441070038; called by muse, mutect2, varscan2
- IL16 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs373808656; called by muse, mutect2
- IL16 | c.3722C>T p.S1241L (on ENST00000302987 / NM_172217.5; = p.S540L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/388 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs373629180; called by muse, mutect2, varscan2
- IL3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 131/287 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs183170475, COSV57308898; called by muse, mutect2, varscan2
- ILDR2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 279/584 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1377515280, COSV54829340; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 172/370 reads (46%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- IMMP1L | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748539826; called by muse, mutect2, varscan2
- IMP4 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 159/352 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777096793, COSV52091651; called by muse, mutect2, varscan2
- INHBA | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 216/464 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54220107; called by muse, mutect2, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 111/268 reads (41%) | catalogued as rs768918635; called by mutect2, varscan2
- INTS11 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1446741527; called by muse, mutect2, varscan2
- IPO11 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 82/189 reads (43%) | catalogued as rs1297677377, COSV57576352; called by muse, mutect2, varscan2
- IQGAP2 | c.1709A>G p.D570G | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57170995; called by muse, mutect2
- IQGAP2 | c.4506-1G>T p.X1502_splice | Splice Site (SNP) | VAF 102/201 reads (51%) | catalogued as COSV99166776; called by muse, mutect2, varscan2
- IQSEC3 | c.1568C>T p.A523V (on ENST00000538872 / NM_001170738.2; = p.A220V on NM_015232.1) | Missense Mutation (SNP) | VAF 360/724 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100407975; called by muse, mutect2
- IRS2 | c.3481G>C p.V1161L | Missense Mutation (SNP) | VAF 287/606 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65478718, COSV65481253; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 159/344 reads (46%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGA3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 112/512 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.888); catalogued as rs1319667630; called by muse, mutect2, varscan2
- ITGAV | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 136/304 reads (45%) | catalogued as rs778721113; called by muse, varscan2
- ITIH4 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV99819606; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 194/366 reads (53%) | catalogued as rs1288961144; called by mutect2, varscan2
- ITSN1 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 199/414 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs781569279, COSV67157825; called by muse, mutect2, varscan2
- JAG2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 225/459 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs191336412; called by muse, mutect2, varscan2
- JAM3 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54456289; called by muse, mutect2, varscan2
- JAML | c.527G>A p.R176H (on ENST00000356289 / NM_001098526.2; = p.R166H on NM_153206.3) | Missense Mutation (SNP) | VAF 126/255 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765722769; called by muse, mutect2, varscan2
- KANK4 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 218/476 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62985323; called by muse, mutect2, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 172/308 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2
- KBTBD11 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 314/649 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57224680; called by muse, varscan2
- KBTBD13 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 311/607 reads (51%) | catalogued as rs766677668; called by muse, mutect2, varscan2
- KCNA10 | c.647del p.R216Lfs*32 | Frame Shift Del (DEL) | VAF 196/467 reads (42%) | catalogued as COSV63905147; called by mutect2, pindel, varscan2
- KCNC1 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 234/496 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56392371; called by muse, mutect2, varscan2
- KCND1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs782418036, COSV54414278; called by muse, mutect2, varscan2
- KCNH1 | c.2159G>A p.R720H (on ENST00000271751 / NM_172362.3; = p.R693H on NM_002238.4) | Missense Mutation (SNP) | VAF 184/370 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs745766834, COSV55085748; called by muse, mutect2, varscan2
- KCNU1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs755168039, COSV67754940; called by muse, mutect2, varscan2
- KCTD13 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 159/367 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV58157114; called by muse, mutect2, varscan2
- KIAA0408 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 165/318 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756491042, COSV100847016, COSV64107131; called by muse, mutect2, varscan2
- KIAA1522 | c.2377G>A p.V793M (on ENST00000373480 / NM_001198972.2; = p.V852M on NM_020888.3) | Missense Mutation (SNP) | VAF 229/520 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99614518; called by muse, mutect2, varscan2
- KIAA1549L | c.5234G>T p.G1745V (on ENST00000321505; = p.G2042V on NM_012194.3) | Missense Mutation (SNP) | VAF 162/356 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58589222; called by muse, mutect2, varscan2
- KIAA1671 | c.4111C>A p.Q1371K | Missense Mutation (SNP) | VAF 18/621 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1311183718; called by muse, mutect2
- KIAA2013 | c.1380del p.L461Cfs*74 | Frame Shift Del (DEL) | VAF 208/503 reads (41%) | catalogued as COSV64860737; called by mutect2, pindel, varscan2
- KIAA2026 | c.4507G>A p.A1503T | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV67356763; called by muse, mutect2, varscan2
- KIF13B | c.4741G>A p.A1581T | Missense Mutation (SNP) | VAF 278/579 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1420025061; called by muse, mutect2, varscan2
- KIF26A | c.3434G>C p.G1145A | Missense Mutation (SNP) | VAF 301/677 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV59464668, COSV59466481; called by muse, mutect2
- KIF26A | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 205/444 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759984495, COSV59467641; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 325/761 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, varscan2
- KLF16 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 274/559 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1483372317, COSV51737011; called by muse, mutect2, varscan2
- KLF5 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 264/527 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV66614131, COSV66614346; called by muse, mutect2, varscan2
- KLHL12 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 168/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1219640111, COSV63042853; called by muse, mutect2, varscan2
- KLHL34 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 325/327 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65279930; called by muse, mutect2, varscan2
- KMT2B | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1232711537, COSV55819574; called by muse, mutect2, varscan2
- KMT2C | c.7789C>G p.P2597A | Missense Mutation (SNP) | VAF 19/547 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51450870; called by muse, mutect2
- KREMEN2 | c.1325C>T p.A442V (on ENST00000303746 / NM_172229.3; = p.R416W on NM_024507.4) | Missense Mutation (SNP) | VAF 231/521 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV99233970; called by muse, mutect2, varscan2
- KRT14 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs755331521; called by muse, mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 93/225 reads (41%) | catalogued as COSV54178849; called by mutect2, pindel, varscan2
- KRT71 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 252/513 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs552558218, COSV57290905; called by muse, mutect2, varscan2
- KRT79 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs772320719; called by muse, mutect2, varscan2
- KRTAP10-4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 301/1291 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs782705931; called by muse, mutect2, varscan2
- KRTAP10-7 | c.450del p.C151Afs*29 | Frame Shift Del (DEL) | VAF 296/770 reads (38%) | catalogued as rs1555928560; called by mutect2, pindel, varscan2
- LAMA2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs1189105467, COSV70339983; called by muse, mutect2, varscan2
- LAMA2 | c.9223C>A p.Q3075K | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771012835, COSV101370876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA3 | c.5467G>A p.D1823N (on ENST00000313654 / NM_198129.4; = p.D214N on NM_000227.6) | Missense Mutation (SNP) | VAF 140/265 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779345110; called by muse, mutect2, varscan2
- LAMA5 | c.8003G>A p.R2668Q | Missense Mutation (SNP) | VAF 299/603 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967471014, COSV53361912; called by muse, mutect2, varscan2
- LAP3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 141/260 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750498172, COSV56898726; called by muse, varscan2
- LBR | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772650538; called by muse, mutect2, varscan2
- LEMD3 | c.2573-1G>T p.X858_splice | Splice Site (SNP) | VAF 115/243 reads (47%) | catalogued as COSV100384336; called by muse, mutect2, varscan2
- LENG8 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 213/451 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201939037; called by muse, mutect2, varscan2
- LETM1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 210/412 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs143969650; called by muse, mutect2, varscan2
- LGALS14 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 180/345 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as COSV100648462; called by muse, mutect2, varscan2
- LILRB1 | c.49_50del p.L17Ifs*53 | Frame Shift Del (DEL) | VAF 126/518 reads (24%) | catalogued as rs753323765; called by pindel, varscan2
- LIMK2 | c.1645T>C p.C549R | Missense Mutation (SNP) | VAF 144/285 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as COSV59182343; called by muse, mutect2, varscan2
- LIN37 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs369644711, COSV50001397; called by muse, mutect2, varscan2
- LIX1L | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553757906; called by muse, mutect2, varscan2
- LMAN2 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 173/337 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759347890, COSV57425358; called by muse, mutect2, varscan2
- LMBRD1 | c.719C>T p.A240V (on ENST00000649011; = p.A218V on NM_018368.4) | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as rs768661855, COSV65298989; called by muse, mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 82/211 reads (39%) | catalogued as rs1443101323; called by mutect2, pindel, varscan2
- LOXL3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 185/384 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1353900393, COSV51214283; called by muse, mutect2, varscan2
- LPAR5 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 326/646 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61692332; called by muse, mutect2, varscan2
- LPIN1 | c.2383T>C p.Y795H | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV56767961; called by muse, mutect2, varscan2
- LRBA | c.5356G>A p.V1786I | Missense Mutation (SNP) | VAF 153/303 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100842324; called by muse, mutect2, varscan2
- LRIG3 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 143/323 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867136273, COSV57862152; called by muse, mutect2, varscan2
- LRIT1 | c.1450A>G p.T484A | Missense Mutation (SNP) | VAF 272/518 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV64512707; called by muse, mutect2, varscan2
- LRP12 | c.1340del p.N447Tfs*41 | Frame Shift Del (DEL) | VAF 172/461 reads (37%) | catalogued as rs1217102319, COSV52630472; called by mutect2, pindel, varscan2
- LRP12 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 163/360 reads (45%) | catalogued as COSV52634522; called by muse, mutect2, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 128/295 reads (43%) | catalogued as COSV55542953; called by muse, mutect2, varscan2
- LRP3 | c.2255dup p.P753Afs*12 | Frame Shift Ins (INS) | VAF 125/386 reads (32%) | catalogued as rs1230631561; called by mutect2, varscan2
- LRRC4C | c.1856G>A p.S619N | Missense Mutation (SNP) | VAF 159/331 reads (48%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV53419726; called by muse, mutect2, varscan2
- LRRC63 | c.76del p.T26Pfs*14 | Frame Shift Del (DEL) | VAF 115/294 reads (39%) | catalogued as rs1319697316; called by mutect2, pindel, varscan2
- LRRC75A | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 149/317 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1355855163; called by muse, mutect2, varscan2
- LRRC8A | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 189/376 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1225279411, COSV52184092; called by muse, mutect2, varscan2
- LRRC8C | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs770087026, COSV64999716; called by muse, mutect2, varscan2
- LRRC9 | c.1940dup p.N647Kfs*14 | Frame Shift Ins (INS) | VAF 101/248 reads (41%) | catalogued as rs769178849; called by mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 88/251 reads (35%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRK2 | c.3568G>T p.E1190* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | catalogued as COSV54168242; called by muse, mutect2, varscan2
- LRRK2 | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145364431, CM081688, CM081690, COSV54145210; ClinVar: uncertain significance; called by muse, varscan2
- LRRTM1 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 241/455 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765524725; called by muse, mutect2, varscan2
- LSM10 | c.362dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 110/312 reads (35%) | catalogued as rs768776995; called by mutect2, pindel, varscan2
- LTBP4 | c.4378G>T p.A1460S (on ENST00000308370 / NM_001042544.1; = p.A1423S on NM_003573.2) | Missense Mutation (SNP) | VAF 286/618 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.097); catalogued as COSV52585561; called by muse, mutect2, varscan2
- LY9 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 151/327 reads (46%) | catalogued as COSV54433550; called by muse, mutect2, varscan2
- LZTS2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 290/579 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs924657673, COSV64651943; called by muse, mutect2, varscan2
- MAD2L1BP | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 245/504 reads (49%) | catalogued as rs777562428; called by muse, mutect2, varscan2
- MAEL | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 149/274 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63306182; called by muse, mutect2, varscan2
- MAN2B2 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767305655; called by muse, varscan2
- MAP2K7 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67608956; called by muse, varscan2
- MAP3K13 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 172/360 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs902931460, COSV53988830; called by muse, mutect2, varscan2
- MAP3K20 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 174/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59102562, COSV59103557; called by muse, mutect2, varscan2
- MAP3K9 | c.2843C>A p.T948N (on ENST00000554752 / NM_001284230.1; = p.T962N on NM_033141.4) | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV67122095; called by muse, varscan2
- MAP4K4 | c.3146C>T p.A1049V (on ENST00000347699 / NM_001242559.2; = p.A967V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56326482; called by muse, mutect2
- MAP6 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774595883, COSV59075108; called by muse, mutect2, varscan2
- MARVELD2 | c.1289dup p.G431Rfs*5 | Frame Shift Ins (INS) | VAF 233/589 reads (40%) | catalogued as rs1283422805; called by mutect2, pindel, varscan2
- MAST2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 206/422 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs749684141, COSV100787959; called by muse, mutect2, varscan2
- MAST4 | c.4558C>T p.R1520C (on ENST00000403625 / NM_001164664.2; = p.R1331C on NM_015183.3) | Missense Mutation (SNP) | VAF 281/591 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1372922287; called by muse, mutect2, varscan2
- MBOAT7 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as rs1240560032; called by muse, mutect2
- MCF2L2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 214/447 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV61052362; called by muse, mutect2, varscan2
- MEDAG | c.539del p.P180Qfs*11 | Frame Shift Del (DEL) | VAF 102/262 reads (39%) | catalogued as rs1368498416, COSV66850199; called by mutect2, pindel, varscan2
- MEGF10 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs553024715; called by muse, mutect2, varscan2
- MEGF8 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 123/309 reads (40%) | catalogued as rs1222471099; called by muse, mutect2, varscan2
- MFN1 | c.401del p.K134Rfs*3 | Frame Shift Del (DEL) | VAF 109/260 reads (42%) | catalogued as rs755881517; called by mutect2, pindel, varscan2
- MFSD1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570607559; called by muse, mutect2, varscan2
- MFSD6L | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 180/404 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as COSV61002178; called by muse, varscan2
- MGA | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 99/190 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs772780139; called by muse, mutect2, varscan2
- MGST3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs764623433; called by muse, mutect2, varscan2
- MIDEAS | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 194/412 reads (47%) | catalogued as COSV54093577; called by muse, varscan2
- MIER1 | c.455G>A p.R152Q (on ENST00000355356 / NM_001077701.3; = p.R169Q on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as rs1166447395; called by muse, mutect2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 148/339 reads (44%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MIGA2 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 334/603 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs763100787; called by muse, mutect2, varscan2
- MITF | c.1075C>T p.R359* (on ENST00000448226 / NM_006722.3; = p.R259* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 242/583 reads (42%) | catalogued as CM960963, COSV100097589; called by muse, mutect2, varscan2
- MIXL1 | c.201del p.A68Pfs*104 | Frame Shift Del (DEL) | VAF 82/234 reads (35%) | catalogued as rs1310131842; called by mutect2, pindel, varscan2
- MKI67 | c.8470C>A p.P2824T | Missense Mutation (SNP) | VAF 190/573 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV64075981; called by muse, mutect2, varscan2
- MKRN1 | c.134del p.G45Afs*44 | Frame Shift Del (DEL) | VAF 274/624 reads (44%) | catalogued as rs1488398510; called by mutect2, pindel, varscan2
- MKRN3 | c.118del p.E40Nfs*21 | Frame Shift Del (DEL) | VAF 209/540 reads (39%) | catalogued as COSV100090874; called by mutect2, pindel, varscan2
- MLC1 | c.639dup p.I214Dfs*8 | Frame Shift Ins (INS) | VAF 150/395 reads (38%) | catalogued as rs1449444164; called by mutect2, pindel, varscan2
- MMP9 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1263490093; called by muse, mutect2, varscan2
- MPP3 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 18/451 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101263362; called by muse, mutect2
- MRPL37 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 171/342 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV60320964; called by muse, mutect2, varscan2
- MRPL9 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 31/610 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1158533080; called by muse, mutect2
- MS4A18 | c.676G>A p.A226T (on ENST00000398983; = p.A228T on NM_001354471.1) | Missense Mutation (SNP) | VAF 186/377 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs960858474; called by muse, mutect2, varscan2
- MTCL1 | c.1846G>A p.A616T (on ENST00000306329 / NM_001378206.1; = p.A256T on NM_015210.4) | Missense Mutation (SNP) | VAF 219/438 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757292748, COSV60403859; called by muse, mutect2, varscan2
- MTCL1 | c.3154C>T p.R1052W (on ENST00000306329 / NM_001378206.1; = p.R733W on NM_015210.4) | Missense Mutation (SNP) | VAF 185/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60414292; called by muse, mutect2, varscan2
- MTF1 | c.2224del p.E742Rfs*90 | Frame Shift Del (DEL) | VAF 182/440 reads (41%) | catalogued as COSV65988475; called by mutect2, pindel, varscan2
- MTHFD1L | c.278del p.N93Tfs*18 | Frame Shift Del (DEL) | VAF 154/412 reads (37%) | catalogued as rs769597461; called by mutect2, pindel, varscan2
- MUC17 | c.9587C>T p.T3196I | Missense Mutation (SNP) | VAF 169/354 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV60279785; called by muse, mutect2, varscan2
- MUC2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0); catalogued as rs1432381237; called by muse, mutect2, varscan2
- MUC4 | c.16102G>A p.A5368T (on ENST00000463781 / NM_018406.7; = p.A1132T on NM_004532.6) | Missense Mutation (SNP) | VAF 373/1031 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1357932793; called by muse, mutect2, varscan2
- MUC4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 361/707 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.494); catalogued as rs1438580385; called by muse, mutect2, varscan2
- MUC4 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 238/553 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as rs759575824; called by muse, mutect2, varscan2
- MUC5B | c.14254C>G p.P4752A | Missense Mutation (SNP) | VAF 198/420 reads (47%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs774333108; called by mutect2, varscan2
- MUTYH | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 176/357 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557476104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.1384del p.E462Rfs*114 | Frame Shift Del (DEL) | VAF 200/455 reads (44%) | catalogued as COSV55141095; called by mutect2, pindel, varscan2
- MYCBPAP | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 207/445 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761217163; called by muse, mutect2, varscan2
- MYH11 | c.5241G>T p.E1747D | Missense Mutation (SNP) | VAF 217/452 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.308); catalogued as COSV55544409; called by muse, mutect2, varscan2
- MYH13 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs377063691; called by muse, mutect2, varscan2
- MYH2 | c.4148C>T p.T1383M | Missense Mutation (SNP) | VAF 174/367 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1456388384, COSV55446746; called by muse, mutect2, varscan2
- MYH4 | c.3635A>G p.D1212G | Missense Mutation (SNP) | VAF 175/349 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs141172847; called by muse, mutect2, varscan2
- MYL2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 100/233 reads (43%) | catalogued as rs1305020660; called by muse, varscan2
- MYO15A | c.9665G>A p.R3222H | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201712137, COSV99233311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 46/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200925200; called by muse, mutect2
- MYO1G | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 245/489 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV51853262, COSV99349192; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 218/545 reads (40%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- MYOM2 | c.2374G>A p.G792S | Missense Mutation (SNP) | VAF 258/497 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34863717, COSV50720369; called by muse, mutect2, varscan2
- NAA16 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 162/308 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769875149, COSV65127991; called by muse, mutect2, varscan2
- NAB1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 199/404 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61609085; called by muse, mutect2, varscan2
- NAV1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 185/375 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs146415554, CM137457; called by muse, mutect2, varscan2
- NBEAL2 | c.4360A>G p.T1454A | Missense Mutation (SNP) | VAF 222/440 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as COSV52757772; called by muse, mutect2, varscan2
- NEB | c.6244G>A p.E2082K | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs372667149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs367919667; called by muse, varscan2
- NFKBID | c.865C>T p.R289W (on ENST00000396901; = p.R441W on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 199/393 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs773657096, COSV61729046; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 185/402 reads (46%) | catalogued as rs1171412241, CD054388; called by mutect2, varscan2
- NIPA1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 249/473 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV61680180; called by muse, mutect2, varscan2
- NKX3-2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs868029446; called by muse, varscan2
- NKX6-2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569871146; called by muse, mutect2, varscan2
- NLGN1 | c.2414A>C p.N805T | Missense Mutation (SNP) | VAF 179/334 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV64341894; called by muse, mutect2, varscan2
- NLGN2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 200/449 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs757491477, COSV56658713; called by muse, mutect2, varscan2
- NLRC3 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 187/405 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs539597311, COSV57089352; called by muse, mutect2, varscan2
- NLRP10 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 274/548 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs201964741, COSV60781159, COSV60781793; called by muse, mutect2, varscan2
- NME4 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs776192267; called by muse, mutect2, varscan2
- NMUR1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 261/480 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs962529763; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 57/121 reads (47%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOS1AP | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as rs1477437491, CM104094, COSV62640166; called by muse, mutect2
- NOTCH2NLA | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.659); catalogued as rs782417251; called by mutect2, varscan2
- NPBWR1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 253/633 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs939933182; called by muse, mutect2, varscan2
- NPY2R | c.796del p.T266Pfs*35 | Frame Shift Del (DEL) | VAF 180/409 reads (44%) | catalogued as rs758758894; called by mutect2, pindel, varscan2
- NRG2 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 186/418 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549739291; called by muse, mutect2, varscan2
- NRG3 | c.2111C>T p.A704V (on ENST00000404547 / NM_001370084.1; = p.A680V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/347 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.666); catalogued as rs367831182; called by muse, mutect2, varscan2
- NRIP1 | c.2507A>G p.D836G | Missense Mutation (SNP) | VAF 173/333 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as rs779601974; called by muse, mutect2, varscan2
- NRROS | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 250/527 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1326793733; called by muse, mutect2, varscan2
- NRXN1 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 45/579 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751509106; called by muse, mutect2
- NRXN3 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 261/555 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs374275388; called by muse, mutect2, varscan2
- NTN4 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 195/352 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as rs376168277, COSV59220679; called by muse, mutect2, varscan2
- NUDCD1 | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 143/310 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53457229; called by muse, mutect2, varscan2
- NUDT22 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 119/256 reads (46%) | catalogued as rs560431443; called by mutect2, varscan2
- NUP85 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs149330582, COSV55458942; called by muse, mutect2, varscan2
- NUTM1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 220/439 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60995577; called by muse, mutect2, varscan2
- NXN | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 199/411 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs779509441; called by muse, mutect2, varscan2
- OBSCN | c.13693del p.A4565Pfs*117 | Frame Shift Del (DEL) | VAF 292/713 reads (41%) | catalogued as COSV52839582; called by mutect2, pindel, varscan2
- OCEL1 | c.289del p.R97Afs*60 | Frame Shift Del (DEL) | VAF 193/495 reads (39%) | catalogued as rs761699990; called by mutect2, pindel, varscan2
- OIT3 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 220/441 reads (50%) | catalogued as rs770133213, COSV61825631; called by muse, mutect2, varscan2
- OLFML3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 269/543 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776489989, COSV57434919; called by muse, mutect2, varscan2
- OPLAH | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 198/417 reads (47%) | catalogued as rs782043072; called by muse, mutect2, varscan2
- OPN4 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 218/423 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767019152; called by muse, mutect2, varscan2
- OPN5 | c.444del p.H148Qfs*22 | Frame Shift Del (DEL) | VAF 136/356 reads (38%) | catalogued as COSV55247486; called by mutect2, pindel, varscan2
- OR10A7 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 181/394 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV58278083; called by muse, mutect2, varscan2
- OR11H12 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 170/1882 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs753575541; called by muse, mutect2
- OR13H1 | c.882del p.D295Mfs*6 | Frame Shift Del (DEL) | VAF 192/268 reads (72%) | catalogued as rs766808182, COSV100088244; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 176/390 reads (45%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1S1 | c.213del p.M72Cfs*25 | Frame Shift Del (DEL) | VAF 134/405 reads (33%) | catalogued as rs761074067, COSV58706814; called by mutect2, pindel, varscan2
- OR2A1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs573150405; called by mutect2, varscan2
- OR2AT4 | c.598del p.Q200Rfs*37 | Frame Shift Del (DEL) | VAF 208/575 reads (36%) | catalogued as rs999134663; called by mutect2, pindel, varscan2
- OR2T6 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 334/677 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100861480; called by muse, mutect2, varscan2
- OR2W3 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 204/433 reads (47%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767980833, COSV64457734; called by muse, mutect2
- OR4E1 | c.853del p.L285Cfs*2 | Frame Shift Del (DEL) | VAF 134/321 reads (42%) | catalogued as rs1312848030; called by mutect2, pindel, varscan2
- OR4N2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs532135396, COSV60051747, COSV60052445; called by muse, varscan2
- OR52B2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 244/491 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774261038, COSV73209479; called by muse, mutect2, varscan2
- OR52W1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 261/493 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756662426, COSV60950726; called by muse, mutect2, varscan2
- OR6K2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 239/463 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs532035184, COSV62743770; called by muse, mutect2, varscan2
- OR8B8 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 259/510 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV60144479; called by muse, mutect2, varscan2
- OR8K1 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 243/577 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs560184936, COSV54403307; called by muse, mutect2
- OS9 | c.789C>T p.A263= | Splice Region (SNP) | VAF 145/334 reads (43%) | catalogued as rs563206099; called by muse, mutect2, varscan2
- OSBPL5 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 180/439 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs547003210; called by muse, mutect2, varscan2
- OTOG | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 154/324 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs774453668; called by muse, mutect2, varscan2
- OTOGL | c.352G>A p.G118S (on ENST00000547103; = p.G109S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs374058556; called by muse, mutect2, varscan2
- OTUD7A | c.2312del p.P771Rfs*216 (on ENST00000307050 / NM_001382637.1; = p.P764Rfs*216 on NM_130901.3) | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs1258615864; called by mutect2, pindel, varscan2
- P3H3 | c.50del p.P17Rfs*9 | Frame Shift Del (DEL) | VAF 64/464 reads (14%) | catalogued as rs1555120763; called by mutect2, pindel, varscan2
- PAGR1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 64/477 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1307498682; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 142/276 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PAPOLG | c.399dup p.E134* | Frame Shift Ins (INS) | VAF 76/199 reads (38%) | catalogued as rs1221757758; called by mutect2, varscan2
- PAQR9 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 266/524 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV61417771; called by muse, mutect2, varscan2
- PARD6G | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 254/498 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs904200168; called by muse, mutect2, varscan2
- PARPBP | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 121/259 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1565910730; called by muse, mutect2, varscan2
- PAX9 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298237496, COSV64062624; called by muse, mutect2
- PC | c.1936dup p.A646Gfs*19 | Frame Shift Ins (INS) | VAF 214/517 reads (41%) | catalogued as rs776366810; called by mutect2, pindel, varscan2
- PCDH1 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 227/482 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1201677468; called by muse, mutect2, varscan2
- PCDH7 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 219/496 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688692; called by muse, mutect2, varscan2
- PCDH8 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 294/564 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV58815291; called by muse, mutect2, varscan2
- PCDH8 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 257/511 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as rs1191118479; called by muse, mutect2, varscan2
- PCDHA12 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV56525069; called by muse, mutect2
- PCDHA13 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 172/326 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.604); catalogued as rs1345451348, COSV56476358; called by muse, mutect2, varscan2
- PCDHA13 | c.1333del p.V445Wfs*4 | Frame Shift Del (DEL) | VAF 277/598 reads (46%) | catalogued as rs1562791192; called by mutect2, varscan2
- PCDHB1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 234/476 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60631214; called by muse, mutect2, varscan2
- PCDHB13 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 182/446 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as rs536260978, COSV99507161; called by muse, varscan2
- PCDHB13 | c.2194del p.L732Ffs*8 | Frame Shift Del (DEL) | VAF 250/578 reads (43%) | catalogued as rs1554288180, COSV53396232; called by mutect2, pindel, varscan2
- PCDHB15 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 228/459 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV50858060; called by muse, mutect2, varscan2
- PCDHGA4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 234/522 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1228836363, COSV53968641; called by muse, mutect2, varscan2
- PCDHGB6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 235/529 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs757628906, COSV53968275; called by muse, mutect2, varscan2
- PCNT | c.7918A>G p.M2640V | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199905581; called by muse, varscan2
- PCNX3 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 198/370 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100482613; called by muse, mutect2, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 173/418 reads (41%) | catalogued as rs768249210; called by mutect2, varscan2
- PDE12 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 210/402 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV60819507; called by muse, mutect2, varscan2
- PDE3A | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 336/650 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs767740035; called by muse, mutect2, varscan2
- PDX1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 227/472 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs761089644, COSV66846968; called by muse, mutect2, varscan2
- PDZD2 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 211/467 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56855660; called by muse, mutect2, varscan2
- PEG3 | c.1662G>T p.Q554H | Missense Mutation (SNP) | VAF 195/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1481723913; called by muse, mutect2, varscan2
- PENK | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 229/472 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV59242575; called by muse, mutect2, varscan2
- PER1 | c.3266G>T p.S1089I | Missense Mutation (SNP) | VAF 132/273 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57920610; called by muse, mutect2, varscan2
- PFKP | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 179/352 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as rs150500285, COSV66899580; called by muse, mutect2, varscan2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 179/462 reads (39%) | catalogued as rs781166611; called by mutect2, pindel, varscan2
- PGBD2 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100251891; called by muse, mutect2, varscan2
- PHACTR3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 332/661 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1374194548, COSV63026926; called by muse, mutect2, varscan2
- PIBF1 | c.33dup p.V12Sfs*5 | Frame Shift Ins (INS) | VAF 108/250 reads (43%) | catalogued as rs925772654; called by mutect2, varscan2
- PIF1 | c.329del p.P110Qfs*63 | Frame Shift Del (DEL) | VAF 273/697 reads (39%) | catalogued as rs1209314898; called by mutect2, pindel, varscan2
- PIFO | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63863707; called by muse, varscan2
- PIGN | c.2381T>C p.L794S | Missense Mutation (SNP) | VAF 115/243 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV104414621; called by muse, mutect2, varscan2
- PIK3R6 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 179/324 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1396636720; called by muse, mutect2, varscan2
- PITPNM2 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 178/482 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54900233; called by muse, mutect2, varscan2
- PITPNM3 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 269/532 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241778920, COSV99338601; called by muse, mutect2, varscan2
- PKD2 | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 202/428 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs370489860, CM127163; called by muse, mutect2, varscan2
- PKNOX2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750281653, COSV53545465; called by muse, mutect2, varscan2
- PKP3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 235/561 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs528553438; called by muse, mutect2, varscan2
- PLA2G5 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs755878705, COSV100908231; called by muse, mutect2, varscan2
- PLA2G7 | c.948dup p.I317Yfs*4 | Frame Shift Ins (INS) | VAF 173/399 reads (43%) | catalogued as rs1363340574; called by mutect2, pindel, varscan2
- PLCB1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs761393253, COSV100571455; ClinVar: uncertain significance; called by muse, mutect2
- PLCH2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 194/467 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745634767; called by muse, mutect2, varscan2
- PLCL1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 213/470 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs370610240; called by muse, mutect2, varscan2
- PLEC | c.13081G>A p.A4361T (on ENST00000322810 / NM_201380.4; = p.A4251T on NM_000445.5) | Missense Mutation (SNP) | VAF 243/480 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs781292412, COSV59643206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
2,619 further variants in this file (1,731 protein-altering or splice-affecting, 738 silent, 150 other) are not listed here.
